Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A74A, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A74A-01A (Primary Tumor).

Patient: XXX

Age:

Gender: F

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Gastric cancer**

Date of admission:

*ICD-O-3
Adenocarcinoma, intestinal type,
tubular (8144/3)
Code to highest 8144/3
Site Stomach NOS C16.9
9/26/13*

Material:

1) Material: stomach. Method of collection: Multiple organ resection

Histopathological diagnosis:

Examination performed on:

Stomach tubular adenocarcinoma
Metastases to 4/11 adjacent lymph nodes.
G2, pT3, pN2. (8140/3 T-63000)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Stomach after being excised along the greater curvature, sized 17 x 15 cm with the omentum sized 21 x 17 cm.
Thickening within the omentum sized 7.5 x 4.2 cm.
Ulcerous tumour in the mucosa sized 8 x 4.5 x 1.3 cm.
The lesion is located 1.2 cm away from the proximal incision line, and 4 cm from the distal one.

Microscopic description:

Tubular adenocarcinoma (G2 acc. to Lauren intestinal type). Tumour infiltrates deeply the subserosa (pT3).
Excision lines are free of cancer (test No. anastomosis ring).
Metastases to 1/4 pericardial lymph nodes, 3/7 greater curvature lymph nodes with the nodular capsule involved.
The omentum free of neoplastic lesions.
During the procedure, material evaluated in tests was also collected.

Assistant:

Pathologist:

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-O Discrepancy		

Source: NCI Genomic Data Commons file f0195d3b-e25f-4931-9e80-92e5fda37188 (TCGA-D7-A74A.EAC25D89-5FB9-4B88-A5AD-9C5A6FD227AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).